Somatic mutation profile of tumor specimen TCGA-EE-A3AH-06A (aliquot TCGA-EE-A3AH-06A-11D-A196-08) from TCGA case TCGA-EE-A3AH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.6 years (14,823 days).
Specimen TCGA-EE-A3AH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aeac620f-5864-4faa-a6ba-9f51094a02a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AH-10A (Blood Derived Normal), aliquot TCGA-EE-A3AH-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/779d6146-6176-4114-9f4c-2f7281946935

The open-access MAF lists 465 somatic variants for this specimen: 324 protein-altering or splice-affecting, 130 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 130, Nonsense Mutation 21, Splice Region 11, Intron 7, Frame Shift Del 5, In Frame Del 4, Splice Site 3, RNA 3, Translation Start Site 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- F9 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 49/52 reads (94%) | catalogued as rs137852272, CM053886, CM940519, CS942012, COSV54379384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- AARS1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV55746664; called by muse, mutect2, varscan2
- ABCA13 | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV70026927; called by muse, mutect2, varscan2
- ABCC3 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV53318951; called by muse, mutect2, varscan2
- ACP2 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57042010; called by muse, mutect2, varscan2
- ACTN4 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV53144271; called by muse, mutect2, varscan2
- ADAD1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs1221669369, COSV56642420; called by muse, varscan2
- ADAM18 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55845381; called by muse, mutect2, varscan2
- ADAMTS20 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs368915817, COSV101240640; called by muse, varscan2
- ADAMTSL3 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54440919; called by muse, varscan2
- ADCY9 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53572980; called by muse, mutect2
- ADGRG4 | c.6805G>A p.E2269K | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs1295700428, COSV54952143, COSV99794496; called by muse, mutect2, varscan2
- ADGRV1 | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV67977923; called by muse, mutect2, varscan2
- ANKRD30A | c.1828-1G>A p.X610_splice (on ENST00000611781; = p.X554_splice on NM_052997.2) | Splice Site (SNP) | VAF 68/81 reads (84%) | catalogued as COSV64606759; called by muse, mutect2, varscan2
- AP2A1 | c.1272C>T p.I424= | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as rs565962932, COSV62817682; called by muse, mutect2, varscan2
- APOB | c.8614G>A p.G2872R | Missense Mutation (SNP) | VAF 336/677 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.368); catalogued as rs267599182, COSV51928800; called by muse, mutect2, varscan2
- ARHGAP10 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs201271675; called by muse, varscan2
- ARHGAP44 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV52391130; called by muse, mutect2, varscan2
- ASTN2 | c.2027C>T p.S676F (on ENST00000313400 / NM_001365069.1; = p.S625F on NM_014010.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV57761542, COSV57791174; called by muse, mutect2, varscan2
- ATF5 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as rs368354899; called by muse, mutect2, varscan2
- ATP13A4 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1299849578, COSV55067498; called by muse, mutect2, varscan2
- ATP6V0D2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV53413775; called by muse, mutect2, varscan2
- AUTS2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 69/109 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV61389989; called by muse, mutect2, varscan2
- BAIAP2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100348749; called by muse, mutect2
- BAZ2B | c.2539A>G p.R847G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58597567; called by muse, mutect2, varscan2
- BCAS3 | c.2080C>T p.P694S (on ENST00000390652 / NM_001353144.2; = p.P679S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs1286020296, COSV66771352; called by muse, mutect2, varscan2
- BRAT1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0.089); catalogued as rs888197625, COSV61394704; called by muse, mutect2, varscan2
- BRICD5 | c.776C>A p.P259Q (on ENST00000562360; = p.P227Q on NM_182563.3) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57027197; called by muse, varscan2
- C10orf71 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60505727; called by muse, mutect2, varscan2
- C15orf32 | n.991G>A | Splice Region (SNP) | VAF 45/107 reads (42%) | catalogued as rs768271793; called by muse, mutect2, varscan2
- C16orf78 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs753731381, COSV54555502; called by muse, mutect2, varscan2
- C4BPA | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65535971; called by muse, mutect2, varscan2
- CACNA1S | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62937781; called by muse, varscan2
- CADM3 | c.662G>A p.R221K (on ENST00000368125 / NM_001127173.3; = p.R255K on NM_021189.5) | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100930399, COSV63684559, COSV63687767; called by muse, mutect2, varscan2
- CAPN13 | c.1513A>T p.I505F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV54429427; called by muse, mutect2, varscan2
- CCDC3 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV66558929; called by muse, mutect2, varscan2
- CCDC57 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV66433291; called by muse, mutect2, varscan2
- CCDC80 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759648511, COSV52815608; called by muse, mutect2, varscan2
- CCR3 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as rs202202009, COSV62462222; called by muse, mutect2, varscan2
- CD200R1 | c.618G>A p.W206* (on ENST00000471858 / NM_170780.3; = p.W229* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV55599758; called by muse, mutect2, varscan2
- CD72 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV52410591; called by muse, mutect2, varscan2
- CDH26 | c.2491C>T p.P831S (on ENST00000348616 / NM_177980.4; = p.P164S on NM_021810.6) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV54844711; called by muse, mutect2, varscan2
- CDH4 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV64646434; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2, varscan2
- CDH9 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs867964392, COSV50259663; called by muse, mutect2, varscan2
- CDR2 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV51675644, COSV99193489; called by muse, varscan2
- CELA3A | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1334774609, COSV51582393; called by muse, mutect2, varscan2
- CERKL | c.1357G>A p.G453R (on ENST00000339098 / NM_001030311.2; = p.G427R on NM_201548.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59205179; called by muse, mutect2, varscan2
- CFAP20DC | c.1403A>C p.E468A (on ENST00000482387 / NM_001351530.2; = p.E343A on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV99919455; called by muse, varscan2
- CFAP20DC | c.1402G>A p.E468K (on ENST00000482387 / NM_001351530.2; = p.E343K on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV99919456; called by muse, varscan2
- CFHR5 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs868484373, COSV56819570; called by muse, mutect2, varscan2
- CFTR | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs562012226, COSV50044478; called by muse, mutect2, varscan2
- CHD9 | c.6713A>G p.N2238S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV54608825; called by muse, mutect2, varscan2
- CIP2A | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV55417797; called by muse, mutect2, varscan2
- CLEC1A | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as rs867777558, COSV59531324; called by muse, mutect2, varscan2
- CLMP | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71649443; called by muse, mutect2, varscan2
- CMYA5 | c.7070G>A p.W2357* | Nonsense Mutation (SNP) | VAF 15/20 reads (75%) | catalogued as rs1425254866, COSV71404681; called by muse, mutect2, varscan2
- CNTN3 | c.2644T>C p.Y882H | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV99725907; called by muse, mutect2, varscan2
- CNTN5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as rs1385144818, COSV54282815, COSV99680319; called by muse, mutect2, varscan2
- CNTNAP4 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs769681418, COSV56671318; called by muse, mutect2, varscan2
- CNTNAP5 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV70478840; called by muse, mutect2, varscan2
- COL16A1 | c.4009C>T p.P1337S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54702561; called by muse, mutect2, varscan2
- COL2A1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV61528952; called by muse, mutect2, varscan2
- COL3A1 | c.4048C>T p.L1350F | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV58584524; called by muse, mutect2, varscan2
- COL4A5 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 73/79 reads (92%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); catalogued as rs779033931, COSV60358544; called by muse, mutect2, varscan2
- COLQ | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101082535, COSV67524336; called by muse, mutect2, varscan2
- CPED1 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV59999017; called by muse, mutect2, varscan2
- CSMD2 | c.4781C>T p.S1594L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs867239715, COSV53891736; called by mutect2, varscan2
- CSPG4 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.046); catalogued as COSV57892620; called by muse, mutect2, varscan2
- CUX2 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55627371; called by muse, mutect2, varscan2
- CYP2B6 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57842937; called by muse, mutect2, varscan2
- CYP2F1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749333476, COSV58526990; called by mutect2, varscan2
- CYP4F8 | c.399G>A p.G133= | Splice Region (SNP) | VAF 15/26 reads (58%) | catalogued as COSV57853513; called by muse, mutect2, varscan2
- DCC | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs1316452152, COSV71428963; called by muse, mutect2, varscan2
- DHRS7B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV60887474; called by muse, mutect2, varscan2
- DHRS9 | c.199A>C p.T67P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV59139360; called by muse, mutect2, varscan2
- DIABLO | c.306C>T p.G102= (on ENST00000443649 / NM_001278303.1; = p.G175= on NM_019887.6) | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as rs753638530, COSV57335981; called by mutect2, varscan2
- DKK1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100906572; called by muse, mutect2, varscan2
- DKK1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100906574; called by muse, mutect2, varscan2
- DLG2 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54630723, COSV54649244; called by muse, mutect2, varscan2
- DMBX1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV63601796; called by muse, mutect2, varscan2
- DPYS | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60907470; called by muse, mutect2, varscan2
- DUSP26 | c.562A>C p.I188L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56361090; called by muse, mutect2, varscan2
- EIF4G1 | c.4621C>T p.L1541= (on ENST00000346169 / NM_198241.3; = p.L1346= on NM_004953.5) | Splice Region (SNP) | VAF 23/41 reads (56%) | catalogued as COSV59989883; called by muse, mutect2, varscan2
- ELAPOR2 | c.2971G>A p.E991K (on ENST00000450689 / NM_001142749.3; = p.E824K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV51885157; called by muse, mutect2, varscan2
- EPB41L3 | c.3050C>G p.T1017S | Missense Mutation (SNP) | VAF 89/103 reads (86%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59447946, COSV59461573; called by muse, mutect2, varscan2
- ERICH3 | c.3955G>A p.D1319N | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs761450225, COSV58602353; called by muse, mutect2, varscan2
- ETS2 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 72/80 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62872589; called by muse, mutect2, varscan2
- FAM47A | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV60495185; called by muse, mutect2, varscan2
- FAT3 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 557/588 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV53090345; called by muse, mutect2, varscan2
- FGD2 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV51462768; called by muse, mutect2, varscan2
- FGF9 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV66644276; called by muse, mutect2, varscan2
- FILIP1 | c.2683G>A p.G895R | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52725516; called by muse, mutect2, varscan2
- FLG2 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV66167370; called by muse, mutect2, varscan2
- FLT4 | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56102355; called by muse, mutect2, varscan2
- FMN2 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.977); catalogued as rs1367043984, COSV60422634; called by muse, mutect2
- FOXK2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV58876994; called by muse, mutect2, varscan2
- FSTL4 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551036078, COSV54766493; called by muse, mutect2, varscan2
- GALNT17 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV61153625; called by muse, mutect2, varscan2
- GALT | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM129685, COSV66592723; called by muse, mutect2, varscan2
- GCOM1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV51088905; called by muse, mutect2, varscan2
- GDF3 | c.159A>C p.K53N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1436355007, COSV61711801; called by muse, mutect2, varscan2
- GFRAL | c.17T>G p.F6C | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV61229767; called by muse, mutect2, varscan2
- GHR | c.876G>A p.R292= | Splice Region (SNP) | VAF 43/71 reads (61%) | catalogued as COSV50141060; called by muse, mutect2, varscan2
- GPR50 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as rs776809214, COSV54437724; called by muse, mutect2, varscan2
- HECW2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.916); catalogued as COSV53653347; called by muse, mutect2, varscan2
- HERC2 | c.9925C>T p.Q3309* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99876498; called by muse, varscan2
- HIPK1 | c.3265C>T p.P1089S (on ENST00000369558 / NM_001369806.1; = p.P695S on NM_181358.2) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61246768; called by muse, mutect2, varscan2
- HJURP | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 69/167 reads (41%) | catalogued as rs752106771, COSV64978532; called by muse, mutect2, varscan2
- HLA-DMB | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1328546953, COSV66870624; called by muse, mutect2, varscan2
- HS3ST3B1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62906227; called by muse, varscan2
- HSD17B6 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs971514245, COSV59107416; called by muse, mutect2
- HSD3B2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV65592816; called by muse, mutect2, varscan2
- HTR7 | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53284516; called by muse, mutect2, varscan2
- HYDIN | c.9946C>T p.L3316F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs574201495, COSV66862762; called by muse, mutect2, varscan2
- ICE1 | c.3559T>C p.Y1187H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1424368599, COSV56821358; called by muse, mutect2
- IGSF10 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs370254145; called by muse, mutect2, varscan2
- IL7R | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57406650; called by muse, mutect2, varscan2
- ILDR1 | c.1235C>T p.P412L (on ENST00000344209 / NM_001199799.2; = p.P368L on NM_175924.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs144533401; called by muse, varscan2
- INTS13 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677579; called by muse, varscan2
- INTS13 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53904898; called by muse, varscan2
- ITIH3 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759335956, COSV69648355; called by muse, mutect2, varscan2
- IZUMO1R | c.455G>A p.W152* (on ENST00000440961; = p.W159* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 20/21 reads (95%) | catalogued as COSV60622326; called by muse, mutect2, varscan2
- JAK1 | c.2798A>T p.Y933F | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV61088988; called by muse, mutect2, varscan2
- JARID2 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as COSV59187093; called by muse, mutect2, varscan2
- JUN | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV64664288, COSV64664642; called by muse, mutect2, varscan2
- KCNB2 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as rs868845914, COSV73049450; called by muse, mutect2, varscan2
- KCNB2 | c.2393C>T p.S798L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV73049451; called by muse, mutect2, varscan2
- KCNJ3 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs773721348, COSV54533570, COSV54533602; called by muse, mutect2, varscan2
- KCTD19 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58571700; called by muse, mutect2, varscan2
- KIF21A | c.2747C>T p.S916F (on ENST00000361418 / NM_001378440.1; = p.S903F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV62768809, COSV62776884; called by muse, mutect2, varscan2
- KIF25 | c.1124C>T p.S375F (on ENST00000354419 / NM_030615.2; = p.S323F on NM_005355.3) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63026890; called by muse, mutect2, varscan2
- KLHL32 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs150244885; called by muse, mutect2, varscan2
- KLK11 | c.307C>T p.H103Y (on ENST00000594768 / NM_144947.3; = p.H71Y on NM_006853.3) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV51576479; called by muse, mutect2, varscan2
- KMT2B | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV55858915; called by muse, mutect2, varscan2
- KRT7 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.183); catalogued as rs373421416, COSV57766519; called by muse, mutect2, varscan2
- KRT73 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs200530085, COSV59838457; called by muse, mutect2, varscan2
- LAG3 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV52566810; called by muse, mutect2, varscan2
- LCOR | c.3086C>T p.S1029L | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs142303354; called by muse, mutect2, varscan2
- LGALS12 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV55369734; called by muse, mutect2, varscan2
- LILRB2 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1256107044, COSV58744151; called by muse, varscan2
- LPA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100307944; called by muse, mutect2, varscan2
- LRRC8D | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV61577534; called by muse, mutect2, varscan2
- LTA4H | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV57382027; called by muse, mutect2, varscan2
- MAPK13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV52982599; called by muse, mutect2, varscan2
- MGAM | c.3232C>T p.P1078S | Missense Mutation (SNP) | VAF 126/195 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs768009854, COSV72074100; called by muse, mutect2, varscan2
- MGAM | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 170/267 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV72074101; called by muse, mutect2, varscan2
- MGST1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs763132041, COSV50566470; called by muse, mutect2, varscan2
- MIDEAS | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV54093549; called by muse, mutect2, varscan2
- MMP1 | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 112/118 reads (95%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59509759; called by muse, mutect2, varscan2
- MNDA | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1002965819, COSV63740277; called by muse, mutect2, varscan2
- MORC2 | c.1812G>A p.E604= (on ENST00000397641 / NM_001303256.3; = p.E542= on NM_014941.3) | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as rs1214680334, COSV53197297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC17 | c.9214G>T p.D3072Y | Missense Mutation (SNP) | VAF 277/408 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV60283446; called by muse, mutect2, varscan2
- MYH1 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV56844131; called by muse, mutect2, varscan2
- MYH2 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.297); catalogued as COSV55431594; called by muse, mutect2, varscan2
- MYH6 | c.4362C>T p.I1454= | Splice Region (SNP) | VAF 14/15 reads (93%) | catalogued as rs1341369908, COSV62448839; called by muse, mutect2, varscan2
- MYO9A | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV61848916; called by muse, mutect2, varscan2
- MYT1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs367847705; called by muse, mutect2, varscan2
- NAV3 | c.5431G>C p.E1811Q (on ENST00000397909 / NM_001024383.2; = p.E1789Q on NM_014903.6) | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57069285, COSV57114531; called by muse, mutect2, varscan2
- NCOR1 | c.6386G>A p.R2129K | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs749125122, COSV51966566; called by muse, mutect2, varscan2
- NEFH | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV60216046; called by muse, mutect2, varscan2
- NEGR1 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60835110; called by mutect2, varscan2
- NELL1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs544001655, COSV54244136, COSV54248983; called by muse, mutect2, varscan2
- NLGN4Y | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs1321867445, COSV52969431; called by muse, mutect2, varscan2
- NOL8 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs375437538; called by muse, mutect2, varscan2
- NRXN1 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV60489661; called by muse, mutect2, varscan2
- NUF2 | c.487T>A p.L163I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV54842782; called by muse, mutect2, varscan2
- NUP210L | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55144322; called by muse, mutect2, varscan2
- OR11G2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62131806, COSV62133077; called by muse, mutect2, varscan2
- OR1B1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59171424; called by muse, mutect2, varscan2
- OR1N2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV65460309, COSV65460395; called by muse, mutect2, varscan2
- OR2M3 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs868120650, COSV71758944; called by muse, varscan2
- OR2T10 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV57896420, COSV57897064; called by muse, mutect2, varscan2
- OR4M1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs754900821, COSV60060127; called by muse, mutect2, varscan2
- OR51B4 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 126/132 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs1236101597, COSV66516972; called by muse, mutect2, varscan2
- OR6B3 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV60113286; called by muse, mutect2, varscan2
- OSMR | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57082611; called by muse, mutect2, varscan2
- OTOGL | c.5773G>A p.D1925N (on ENST00000547103; = p.D1916N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV54014944; called by muse, mutect2, varscan2
- PADI6 | c.1182G>A p.L394= | Splice Region (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100640009, COSV100640034; called by muse, mutect2, varscan2
- PAPPA | c.4826G>T p.R1609L | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100073972, COSV60279510; called by muse, mutect2, varscan2
- PAQR6 | c.609G>A p.R203= (on ENST00000292291 / NM_001272108.2; = p.R97= on NM_024897.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 37/80 reads (46%) | catalogued as COSV52744582; called by muse, mutect2, varscan2
- PASD1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 67/75 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs1326672678, COSV64854565; called by muse, mutect2, varscan2
- PATJ | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1230481578, COSV57158081; called by muse, mutect2, varscan2
- PCED1A | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); catalogued as COSV100642938; called by muse, mutect2, varscan2
- PCLO | c.15236C>T p.S5079L | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750960950, COSV61623630, COSV61653389; called by muse, mutect2, varscan2
- PCLO | c.14304G>A p.W4768* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as COSV61623635; called by muse, mutect2, varscan2
- PDE4B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs1235753982, COSV58470268; called by muse, mutect2, varscan2
- PDE4DIP | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV57685000; called by muse, mutect2, varscan2
- PDZD8 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100559577, COSV100559622; called by muse, mutect2, varscan2
- PDZD8 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100559624; called by muse, mutect2, varscan2
- PHF3 | c.5327C>T p.P1776L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV50315146; called by muse, mutect2, varscan2
- PIK3R5 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as COSV52651668; called by muse, mutect2, varscan2
- PKD2L1 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 41/43 reads (95%) | catalogued as rs868223368, COSV58395172, COSV58398876; called by muse, mutect2, varscan2
- PLA2G6 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV59268603; called by muse, mutect2, varscan2
- PLCG2 | c.2525A>C p.D842A | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.423); catalogued as COSV63868145; called by muse, mutect2, varscan2
- PLCXD2 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV67338930; called by muse, mutect2, varscan2
- PLXNA4 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.689); catalogued as rs1429028462, COSV58113783; called by muse, mutect2, varscan2
- PMFBP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs777864763, COSV52821932; called by muse, mutect2, varscan2
- POU1F1 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV60155334; called by muse, mutect2, varscan2
- PPFIA2 | c.3664G>A p.G1222R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100335019; called by muse, mutect2, varscan2
- PRB2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs746517230, COSV66982607; called by muse, varscan2
- PRDM16 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1328798528, COSV54583566; called by muse, varscan2
- PRDM9 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57002306, COSV57004214; called by muse, mutect2, varscan2
- PREX2 | c.3811C>T p.L1271F | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55759039; called by muse, mutect2, varscan2
- PRKAR2A | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV55551276; called by muse, mutect2, varscan2
- PRKD2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs1445769377, COSV99354610; called by muse, mutect2, varscan2
- PRKDC | c.8554C>T p.P2852S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV58047400; called by muse, mutect2, varscan2
- PRKRIP1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61349624; called by muse, mutect2, varscan2
- PROM2 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs369488555, COSV58297400; called by muse, mutect2, varscan2
- PSG11 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs375462400; called by muse, mutect2, varscan2
- PSKH2 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV52609782; called by muse, mutect2, varscan2
- PTPRC | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.613); catalogued as COSV61408509; called by muse, mutect2, varscan2
- PTPRN2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs768772921, COSV67029090; called by muse, varscan2
- RARRES2 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 450/706 reads (64%) | catalogued as COSV56230986; called by muse, mutect2, varscan2
- RBFOX1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs1354114119, COSV60946236; called by muse, mutect2, varscan2
- RBMY1A1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100385544; called by muse, mutect2, varscan2
- ROS1 | c.6710G>A p.G2237E | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs564889461, COSV63853137, COSV63854641; called by muse, mutect2, varscan2
- RP1 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55112914; called by muse, mutect2, varscan2
- RTP5 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV58319412; called by muse, mutect2, varscan2
- RUNDC1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.556); catalogued as COSV64511603; called by muse, mutect2, varscan2
- SALL1 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs777889848, COSV51755073; called by muse, mutect2, varscan2
- SCN10A | c.4168G>A p.D1390N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV71860772; called by muse, mutect2, varscan2
- SCN10A | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71860773, COSV71861985; called by muse, varscan2
- SCN3A | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV51805184, COSV99328453; called by muse, mutect2, varscan2
- SCN4A | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71126105; called by muse, mutect2, varscan2
- SDK1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as rs1048895252, COSV67360963; called by muse, varscan2
- SEC16B | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100381898; called by muse, mutect2, varscan2
- SEC16B | c.1132G>T p.G378W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381901; called by muse, mutect2, varscan2
- SEC24A | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1050095391, COSV59746342; called by muse, mutect2, varscan2
- SEMG2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as COSV65647261; called by muse, mutect2, varscan2
- SERPINA4 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs374950590; called by muse, mutect2, varscan2
- SERPINB13 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54027922; called by muse, mutect2, varscan2
- SETD1A | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52685990; called by muse, mutect2, varscan2
- SEZ6 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV57979700, COSV57984445; called by muse, mutect2
- SF3B2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs542236228, COSV100488632, COSV59428298; called by muse, varscan2
- SLC13A1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs773673398, COSV52009439; called by muse, mutect2, varscan2
- SLC17A3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100399434, COSV57759720; called by muse, mutect2, varscan2
- SLC25A3 | c.880G>A p.E294K (on ENST00000228318 / NM_005888.3; = p.E293K on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.174); catalogued as COSV51844670, COSV51846288; called by muse, mutect2, varscan2
- SLC25A6 | c.846G>T p.M282I | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1285886159, COSV58430471, COSV58432197; called by muse, mutect2, varscan2
- SLC6A20 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760061013, COSV62070676; called by muse, mutect2, varscan2
- SLFN5 | c.1892C>T p.T631I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55480231; called by muse, mutect2, varscan2
- SNRNP48 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60938975; called by muse, mutect2, varscan2
- SOGA3 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1324685516, COSV64105666; called by muse, varscan2
- SORCS2 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772479245, COSV61165718; called by muse, mutect2, varscan2
- SP100 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60842798; called by muse, mutect2, varscan2
- SPHKAP | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs916908075, COSV60872513; called by muse, mutect2, varscan2
- SPNS1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100209263; called by muse, mutect2, varscan2
- SPTA1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV63750677; called by muse, varscan2
- SPTLC3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV65464388; called by muse, mutect2, varscan2
- SSTR3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100142881; called by muse, mutect2
- STAG1 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52604889; called by muse, mutect2, varscan2
- STAT4 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61828763; called by muse, mutect2, varscan2
- STOX1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53813785; called by muse, mutect2, varscan2
- STXBP5L | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs760015859, COSV56505562; called by muse, mutect2, varscan2
- STXBP5L | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56505572; called by muse, varscan2
- STXBP5L | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV56501760; called by muse, mutect2, varscan2
- SYT10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767119363, COSV57338723; called by muse, mutect2, varscan2
- SYTL5 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV52899397; called by muse, mutect2, varscan2
- TAGLN3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1180200425, COSV56327544; called by muse, mutect2, varscan2
- TBC1D14 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV101299034; called by muse, mutect2, varscan2
- TDRD1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs1564947677, COSV52588995; called by muse, mutect2, varscan2
- TESK2 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.708); catalogued as rs1249858383, COSV59150389; called by muse, mutect2, varscan2
- TET2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.276); catalogued as COSV54403494; called by muse, mutect2, varscan2
- THEMIS | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV64069772; called by muse, mutect2, varscan2
- TMC2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62650999; called by muse, mutect2, varscan2
- TMEM132B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54748390; called by muse, mutect2, varscan2
- TMEM144 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99646970; called by muse, mutect2, varscan2
- TMEM74 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52462832; called by muse, mutect2, varscan2
- TNKS1BP1 | c.5035C>T p.Q1679* | Nonsense Mutation (SNP) | VAF 41/42 reads (98%) | catalogued as COSV64100417; called by muse, mutect2, varscan2
- TNRC6B | c.4686C>A p.F1562L (on ENST00000454349 / NM_001162501.2; = p.F1452L on NM_015088.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.937); catalogued as COSV57291658; called by muse, mutect2, varscan2
- TPH2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV61591114; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1909A>G p.R637G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100967042; called by muse, varscan2
- TRAF3IP1 | c.1910G>A p.R637K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100967044; called by muse, varscan2
- TREM1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs368519218; called by muse, mutect2, varscan2
- TRIM24 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 99/154 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as COSV58970481; called by muse, mutect2, varscan2
- TSC2 | c.5269G>A p.E1757K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1060500957, COSV51912980; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TSPAN13 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100018179; called by muse, mutect2, varscan2
- TTN | c.49313C>T p.A16438V (on ENST00000591111; = p.A9014V on NM_003319.4) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | PolyPhen probably damaging (0.997); catalogued as COSV100592590, COSV59951149; called by muse, mutect2, varscan2
- TTN | c.39166G>A p.E13056K (on ENST00000591111; = p.E5632K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | PolyPhen probably damaging (0.994); catalogued as rs1356852922, COSV59905230; called by muse, mutect2, varscan2
- TTN | c.11257G>A p.E3753K (on ENST00000591111; = p.E3707K on NM_003319.4) | Missense Mutation (SNP) | VAF 81/193 reads (42%) | catalogued as rs397517830, CM1413163, COSV60378308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.8458C>T p.H2820Y (on ENST00000591111; = p.H2774Y on NM_003319.4) | Missense Mutation (SNP) | VAF 68/122 reads (56%) | PolyPhen probably damaging (0.994); catalogued as COSV59951218; called by muse, mutect2, varscan2
- TTN | c.2128G>A p.D710N (on ENST00000591111; = p.D664N on NM_003319.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | PolyPhen probably damaging (0.998); catalogued as COSV100636195, COSV59951260; called by muse, mutect2, varscan2
- TXK | c.69G>A p.K23= | Splice Region (SNP) | VAF 24/48 reads (50%) | catalogued as COSV51913641; called by muse, mutect2, varscan2
- UBE2O | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60061381; called by muse, mutect2, varscan2
- UGT3A2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV56929227; called by muse, mutect2, varscan2
- UPK3B | c.842C>T p.P281L (on ENST00000257632; = p.P253S on NM_001347684.2) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV57536395; called by muse, mutect2, varscan2
- USF3 | c.5687C>T p.P1896L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as rs750257025, COSV57070955, COSV57074512; called by muse, mutect2, varscan2
- USP17L2 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1456864120, COSV61555645; called by muse, mutect2, varscan2
- USP17L2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1211441815, COSV100414719; called by mutect2, varscan2
- UTS2 | c.25T>G p.L9V | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs759578328, COSV99276932; called by muse, mutect2, varscan2
- VPS13D | c.12880G>A p.D4294N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV50628048; called by muse, mutect2, varscan2
- WDR49 | c.1213G>A p.D405N (on ENST00000308378 / NM_001366158.1; = p.D746N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57704933; called by muse, mutect2, varscan2
- WDR75 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV59105001; called by muse, mutect2, varscan2
- XRN1 | c.3016C>T p.Q1006* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV53809418; called by muse, mutect2, varscan2
- XRRA1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1199073919, COSV58496868; called by muse, mutect2
- ZC3H12D | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV66323913; called by muse, mutect2, varscan2
- ZDHHC20 | c.1016C>T p.S339F (on ENST00000400590 / NM_001330059.2; = p.S338F on NM_153251.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV57184815; called by muse, mutect2, varscan2
- ZNF112 | c.1031C>T p.S344F (on ENST00000337401 / NM_001083335.2; = p.S338F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1408723519, COSV61619308; called by muse, mutect2, varscan2
- ZNF155 | c.868T>C p.C290R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54206390; called by muse, mutect2, varscan2
- ZNF160 | c.1089T>A p.H363Q | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61999179; called by muse, mutect2, varscan2
- ZNF205 | c.485-1G>A p.X162_splice | Splice Site (SNP) | VAF 34/138 reads (25%) | catalogued as COSV99530603; called by muse, mutect2, varscan2
- ZNF479 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100482551, COSV100482558; called by muse, mutect2
- ZNF600 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as COSV57741924; called by muse, mutect2, varscan2
- ZNF616 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57510109; called by muse, mutect2, varscan2
- ZNF664 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV61877441; called by muse, mutect2, varscan2
- ZNF804A | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs202247802, COSV56436947, COSV56445554; called by muse, mutect2, varscan2
- ZNF93 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 23/35 reads (66%) | catalogued as COSV59374697; called by muse, mutect2, varscan2
- ZSCAN31 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.268); catalogued as COSV60180498, COSV60180760; called by muse, mutect2, varscan2
- ASAH2 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 64/72 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- CAMK2D | c.856_858del p.E286del | In Frame Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- CDH19 | c.607_609del p.T203del | In Frame Del (DEL) | VAF 25/31 reads (81%) | called by pindel, varscan2
- CENPL | c.931_932del p.V311Sfs*6 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CRMP1 | c.1281+1_1281+5del p.X427_splice | Splice Site (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- FCGBP | c.10976G>A p.G3659E | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MCPH1 | c.1273dup p.Y425Lfs*8 | Frame Shift Ins (INS) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- NCKAP1 | c.2582_2597del p.S861Lfs*12 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.219_220del p.R74Tfs*3 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- RNF123 | c.131_138del p.S44* | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- SYNCRIP | c.1793_1795del p.G598del | In Frame Del (DEL) | VAF 36/90 reads (40%) | called by pindel, varscan2
- SYNE3 | c.766_769delinsCAA p.T256Qfs*50 | Frame Shift Del (DEL) | VAF 30/36 reads (83%) | called by pindel, varscan2*
- SYTL5 | c.1233_1235del p.L412del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- ABCB11 | c.2673C>T p.I891= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV55587600; called by muse, mutect2, varscan2
- ACD | c.153C>T p.L51= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs1207134820, COSV54665585, COSV54667112, COSV54669526; called by muse, mutect2
- ACSF3 | c.438C>T p.V146= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs1381436509, COSV58077325; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1152C>T p.F384= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV56473968; called by muse, mutect2, varscan2
- ADAMTS10 | c.693G>A p.L231= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV54353007; called by muse, mutect2, varscan2
- ADGRL3 | c.3144G>A p.R1048= (on ENST00000506720 / NM_001322402.2; = p.R980= on NM_015236.6) | Silent (SNP) | VAF 67/168 reads (40%) | catalogued as COSV72230017; called by muse, mutect2, varscan2
- ADH6 | c.177G>A p.L59= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV52955553; called by muse, mutect2, varscan2
- ALKBH7 | c.570C>T p.R190= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs1009879215, COSV55531925; called by muse, varscan2
- ARAP2 | c.4857G>A p.K1619= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV58284361; called by muse, mutect2, varscan2
- ATR | c.5895C>T p.S1965= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs755816184, COSV63385148; called by muse, varscan2
- BAIAP2 | c.765C>T p.P255= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs769846726, COSV100348753; called by mutect2, varscan2
- C1QTNF9 | c.717G>A p.G239= | Silent (SNP) | VAF 63/169 reads (37%) | catalogued as COSV59656695; called by muse, mutect2, varscan2
- CD163 | c.1635C>T p.F545= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV63130680; called by muse, mutect2, varscan2
- CDC25B | c.345C>T p.S115= (on ENST00000245960 / NM_021873.3; = p.S101= on NM_004358.4) | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV55654661; called by muse, mutect2, varscan2
- CGNL1 | c.1986G>A p.V662= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55565133; called by muse, mutect2, varscan2
- CHRM2 | c.1149G>A p.K383= | Silent (SNP) | VAF 82/126 reads (65%) | catalogued as COSV57768197, COSV57768512; called by muse, mutect2, varscan2
- CIITA | c.729C>T p.I243= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV100162222, COSV60855248; called by muse, mutect2, varscan2
- CNGA2 | c.282C>T p.F94= | Silent (SNP) | VAF 19/19 reads (100%) | catalogued as COSV61703764; called by muse, mutect2, varscan2
- CNTN3 | c.2643T>G p.A881= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as COSV55178333; called by muse, mutect2, varscan2
- CNTN4 | c.1335G>A p.R445= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV61870034; called by muse, mutect2, varscan2
- COL1A2 | c.2706T>C p.P902= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as COSV51955213; called by muse, mutect2, varscan2
- COL6A6 | c.1458G>A p.L486= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as COSV62020738; called by muse, mutect2, varscan2
- COLGALT1 | c.1644C>T p.A548= | Silent (SNP) | VAF 105/207 reads (51%) | catalogued as rs1193830499, COSV53108078; called by muse, mutect2, varscan2
- CORO2B | c.831C>T p.F277= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as rs946604170, COSV55951411, COSV55952198; called by muse, mutect2, varscan2
- CTLA4 | c.405C>T p.Y135= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV55591966; called by muse, mutect2, varscan2
- CYP2F1 | c.543C>T p.S181= | Silent (SNP) | VAF 88/183 reads (48%) | catalogued as COSV58526985; called by muse, mutect2, varscan2
- DGKI | c.2028C>T p.P676= | Silent (SNP) | VAF 143/235 reads (61%) | catalogued as COSV55942219; called by muse, mutect2, varscan2
- DHRS7C | c.546G>A p.G182= (on ENST00000330255 / NM_001220493.2; = p.G181= on NM_001105571.3) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV57650120; called by muse, mutect2, varscan2
- DNAH5 | c.2013G>A p.L671= | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV54212849; called by muse, mutect2, varscan2
- DNAH7 | c.10779G>A p.R3593= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV56756971; called by muse, mutect2, varscan2
- DNAH8 | c.13020G>A p.G4340= | Silent (SNP) | VAF 82/202 reads (41%) | catalogued as COSV59433677; called by muse, mutect2, varscan2
- DNAJC18 | c.204G>A p.E68= | Silent (SNP) | VAF 20/20 reads (100%) | catalogued as COSV57415423; called by muse, mutect2, varscan2
- DOCK3 | c.1902G>A p.G634= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV56510748; called by muse, mutect2, varscan2
- DSCAM | c.1311G>A p.T437= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as COSV68023458; called by muse, mutect2, varscan2
- DSCAM | c.252C>T p.F84= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as rs747859049, COSV68631659; called by muse, mutect2, varscan2
- EHMT1 | c.3594C>T p.F1198= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV66044639; called by mutect2, varscan2
- ENTPD5 | c.1107C>T p.F369= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as COSV58221140; called by muse, mutect2, varscan2
- EPPK1 | c.2541G>A p.R847= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV73260921; called by muse, mutect2, varscan2
- F13A1 | c.1677C>T p.T559= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV53555855; called by muse, mutect2
- FAM135B | c.4176C>T p.F1392= | Silent (SNP) | VAF 93/218 reads (43%) | catalogued as rs1254801268, COSV52713498; called by muse, mutect2, varscan2
- FAM171A1 | c.522C>T p.S174= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as rs1176794384, COSV65314471; called by muse, mutect2, varscan2
- FAM83H | c.165C>T p.F55= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs1450888924, COSV66353637; called by muse, mutect2, varscan2
- FCGBP | c.6957C>T p.A2319= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as rs1407171784; called by muse, mutect2, varscan2
- FGF12 | c.714G>A p.V238= (on ENST00000454309 / NM_021032.5; = p.V176= on NM_004113.6) | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as rs374897358, COSV53157944, COSV53167484; called by muse, mutect2, varscan2
- FKRP | c.1371C>T p.F457= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1270459605, COSV59358424; called by muse, mutect2, varscan2
- FZD2 | c.1314C>T p.L438= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV59528439; called by muse, varscan2
- GABRP | c.453C>T p.A151= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs752214918, COSV54661951; called by muse, mutect2, varscan2
- GPX6 | c.474G>A p.P158= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1234071872, COSV62657158; called by muse, mutect2, varscan2
- HERC2 | c.9924C>T p.G3308= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1354987008, COSV99876506; called by muse, varscan2
- HLA-DPB1 | c.552C>T p.I184= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs376906908; called by muse, varscan2
- HOXA1 | c.252G>A p.G84= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as rs765261087, COSV56065636, COSV56066067; called by muse, mutect2, varscan2
- HYDIN | c.6885G>A p.E2295= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV59252645; called by muse, mutect2, varscan2
- IFNA17 | c.333A>G p.E111= | Silent (SNP) | VAF 62/80 reads (78%) | catalogued as rs760235895, COSV69738117; called by muse, mutect2, varscan2
- IFT140 | c.1338C>T p.I446= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs781745982, COSV68486838; called by muse, mutect2, varscan2
- IGLL1 | c.495C>T p.P165= | Silent (SNP) | VAF 65/119 reads (55%) | catalogued as rs374132554; called by muse, mutect2, varscan2
- ILDR1 | c.1236C>T p.P412= (on ENST00000344209 / NM_001199799.2; = p.P368= on NM_175924.4) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs769151171, COSV99878924; called by muse, varscan2
- ILDR1 | c.1128C>T p.F376= (on ENST00000344209 / NM_001199799.2; = p.F332= on NM_175924.4) | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV56548787; called by muse, varscan2
- IQGAP3 | c.1677C>T p.L559= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV63250263; called by muse, mutect2, varscan2
- ITGB8 | c.618G>A p.R206= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV56006224; called by muse, mutect2, varscan2
- KCNG4 | c.1032C>T p.I344= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57583141; called by mutect2, varscan2
- KLHL30 | c.1425C>T p.L475= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1178915104, COSV59974907; called by muse, mutect2, varscan2
- LHFPL6 | c.129C>T p.S43= | Silent (SNP) | VAF 73/85 reads (86%) | catalogued as COSV65444504; called by muse, mutect2, varscan2
- LILRA4 | c.753C>T p.I251= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV52491040; called by muse, mutect2, varscan2
- LRRN2 | c.2082G>A p.R694= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as rs769207725, COSV100912880, COSV65783423; called by muse, mutect2, varscan2
- MAG | c.1554C>T p.G518= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs200430942, COSV62699711; called by muse, mutect2, varscan2
- MICALL2 | c.2643C>T p.L881= | Silent (SNP) | VAF 64/99 reads (65%) | catalogued as COSV52514796; called by muse, mutect2, varscan2
- MRC1 | c.327G>A p.G109= | Silent (SNP) | VAF 195/225 reads (87%) | catalogued as rs781790477; called by muse, varscan2
- MUC16 | c.36783C>T p.V12261= | Silent (SNP) | VAF 70/163 reads (43%) | catalogued as COSV67454060; called by muse, mutect2, varscan2
- MXRA5 | c.180C>T p.I60= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as COSV54229068, COSV54250951; called by muse, mutect2, varscan2
- MYCT1 | c.330G>A p.R110= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV65891006; called by muse, mutect2, varscan2
- MYH13 | c.3007C>T p.L1003= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV52823292; called by muse, mutect2, varscan2
- MYH8 | c.1875C>T p.S625= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV67961812, COSV67966288; called by muse, mutect2, varscan2
- MYO1G | c.168C>T p.P56= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV51853913; called by muse, mutect2, varscan2
- NLGN4Y | c.975G>A p.E325= | Silent (SNP) | VAF 34/34 reads (100%) | catalogued as COSV59294839; called by muse, mutect2, varscan2
- NOVA1 | c.1212C>T p.P404= | Silent (SNP) | VAF 28/32 reads (88%) | catalogued as rs200046551, COSV57474008, COSV99947024; called by muse, mutect2, varscan2
- OR14K1 | c.147G>A p.L49= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV99315445, COSV99315519; called by muse, mutect2, varscan2
- OR2A12 | c.810G>A p.R270= | Silent (SNP) | VAF 116/368 reads (32%) | catalogued as COSV68821160; called by muse, mutect2, varscan2
- OR2M3 | c.885G>A p.K295= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV71758945; called by muse, mutect2, varscan2
- OR4N2 | c.480G>A p.V160= | Silent (SNP) | VAF 60/154 reads (39%) | catalogued as COSV60050610; called by muse, varscan2
- OR52B2 | c.447C>T p.A149= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as rs369907116; called by muse, mutect2, varscan2
- OR5B12 | c.795C>T p.F265= | Silent (SNP) | VAF 42/44 reads (95%) | catalogued as COSV56904364, COSV56907044; called by muse, mutect2, varscan2
- P3H2 | c.1707G>A p.Q569= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100078725, COSV60019613; called by muse, mutect2, varscan2
- PARM1 | c.501G>A p.E167= | Silent (SNP) | VAF 112/246 reads (46%) | catalogued as COSV56651551; called by muse, mutect2, varscan2
- PBLD | c.219G>T p.A73= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV53265545; called by muse, mutect2, varscan2
- PCDHB10 | c.663C>T p.S221= | Silent (SNP) | VAF 43/46 reads (93%) | catalogued as COSV53376835; called by muse, mutect2, varscan2
- PCDHGA5 | c.696C>T p.V232= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV53917997; called by muse, mutect2, varscan2
- PCED1A | c.1341C>T p.A447= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100642939; called by muse, mutect2, varscan2
- PDE1C | c.174C>T p.I58= | Silent (SNP) | VAF 139/225 reads (62%) | catalogued as rs751411917, COSV68806435; called by muse, mutect2, varscan2
- PDGFC | c.186G>A p.R62= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56846810; called by muse, mutect2, varscan2
- PGK2 | c.312G>A p.V104= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV59163271, COSV59165211; called by muse, mutect2, varscan2
- PLPP7 | c.159T>G p.G53= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV64835874; called by muse, mutect2, varscan2
- PRAMEF12 | c.444C>T p.I148= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs201538037; called by muse, varscan2
- PRAMEF18 | c.246G>A p.V82= | Silent (SNP) | VAF 68/376 reads (18%) | catalogued as rs1396014515; called by muse, mutect2, varscan2
- PRAMEF6 | c.573C>T p.P191= | Silent (SNP) | VAF 7/15 reads (47%) | called by mutect2, varscan2
- PRKD2 | c.1353C>T p.S451= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs775446787, COSV52187020; called by muse, mutect2, varscan2
- PRKG2 | c.1392C>T p.F464= | Silent (SNP) | VAF 99/117 reads (85%) | catalogued as rs751038377, COSV52321330; called by muse, mutect2, varscan2
- PRPS1L1 | c.477C>T p.I159= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs868370327, COSV72649849; called by muse, mutect2, varscan2
- PTPRC | c.1359G>A p.T453= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs776904542, COSV61407101; called by muse, mutect2, varscan2
- PTPRD | c.4708T>C p.L1570= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV61934451; called by muse, mutect2, varscan2
- PWWP3B | c.405G>A p.R135= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV61798830; called by muse, mutect2, varscan2
- RBM17 | c.804G>A p.E268= | Silent (SNP) | VAF 31/34 reads (91%) | catalogued as COSV65913738, COSV65913983; called by muse, mutect2, varscan2
- RELN | c.6147G>A p.A2049= | Silent (SNP) | VAF 40/57 reads (70%) | catalogued as rs116750302, COSV100634418, COSV58985680; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- REN | c.906C>T p.T302= | Silent (SNP) | VAF 94/260 reads (36%) | catalogued as COSV65817526; called by muse, mutect2, varscan2
- RNF111 | c.1557C>T p.H519= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV62084549; called by muse, mutect2, varscan2
- RNF165 | c.660C>T p.F220= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as rs146872731; called by muse, mutect2, varscan2
- RPS6KA6 | c.1926C>T p.F642= | Silent (SNP) | VAF 41/43 reads (95%) | catalogued as COSV53117780, COSV53118116; called by muse, mutect2, varscan2
- RPS6KC1 | c.406T>C p.L136= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV65298014; called by muse, mutect2, varscan2
- S100A16 | c.126C>T p.L42= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV64182764; called by muse, mutect2, varscan2
- SEZ6 | c.84G>A p.G28= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100253492; called by muse, mutect2
- SF3B2 | c.1008C>T p.P336= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV59428672; called by muse, varscan2
- SLC2A14 | c.1518G>A p.G506= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV61585958; called by muse, mutect2, varscan2
- SLC2A3 | c.1446G>A p.E482= | Silent (SNP) | VAF 58/298 reads (19%) | catalogued as COSV50001307; called by muse, varscan2
- SLCO2A1 | c.1176C>T p.F392= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60484443; called by muse, mutect2, varscan2
- SMC2 | c.3543G>A p.K1181= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs144844202, COSV53964889; called by muse, mutect2, varscan2
- SPEN | c.2595G>A p.E865= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV65359392; called by muse, mutect2, varscan2
- SSTR3 | c.1098G>A p.K366= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1176069914, COSV100142882; called by muse, mutect2, varscan2
- THBS1 | c.1980C>T p.N660= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs148609363; called by muse, mutect2, varscan2
- TMEM144 | c.213G>A p.G71= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as COSV99646969; called by muse, mutect2, varscan2
- TNC | c.102G>A p.Q34= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs761588080, COSV60782465; called by muse, mutect2, varscan2
- TSPAN13 | c.294C>T p.A98= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs770356910, COSV100018185; called by muse, mutect2, varscan2
- TTLL2 | c.1624C>T p.L542= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV53443013; called by muse, mutect2, varscan2
- USH2A | c.1371G>A p.L457= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs1054796812, COSV56343341; called by muse, mutect2, varscan2
- YIPF1 | c.222C>T p.S74= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs267598650, COSV50776464; called by muse, mutect2, varscan2
- ZNF184 | c.1446C>T p.A482= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1184966515, COSV53003683; called by muse, varscan2
- ZNF23 | c.1416G>A p.G472= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV61840660; called by muse, mutect2, varscan2
- ZNF518B | c.2736G>A p.K912= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as rs1560168070, COSV100457003, COSV58721858; called by muse, mutect2, varscan2
- ZNF780B | c.2490C>T p.F830= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV55462735; called by muse, mutect2, varscan2
- ZNF786 | c.1779C>T p.F593= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs749070939, COSV60275389; called by muse, mutect2, varscan2
- ZNF83 | c.1530G>A p.K510= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV56528956; called by muse, mutect2, varscan2
- CR1 | c.487+12239C>T | Intron (SNP) | VAF 33/205 reads (16%) | catalogued as COSV100888007; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722870 G>A | 5'Flank (SNP) | VAF 9/24 reads (38%) | catalogued as rs1240681880, COSV59433666; called by muse, mutect2, varscan2
- FAM86C1P | n.183-1619T>G | Intron (SNP) | VAF 35/38 reads (92%) | catalogued as COSV60638584; called by muse, mutect2, varscan2
- GAD1 | c.1120-603G>A | Intron (SNP) | VAF 28/46 reads (61%) | catalogued as rs1459939347; called by muse, mutect2, varscan2
- HMGB1P1 | n.497G>A | RNA (SNP) | VAF 13/30 reads (43%) | catalogued as rs775241210; called by muse, mutect2, varscan2
- MIR520G | n.14C>T | RNA (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- NRP1 | c.1759+1376G>A | Intron (SNP) | VAF 21/30 reads (70%) | catalogued as rs555823134, COSV99589533; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2466G>A | RNA (SNP) | VAF 8/14 reads (57%) | catalogued as rs1202779198; called by muse, mutect2, varscan2
- THSD4 | c.1016-70386G>A | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- TNPO2 | c.1496+97C>T | Intron (SNP) | VAF 46/105 reads (44%) | catalogued as rs1421233951, COSV63508780; called by muse, mutect2, varscan2
- VPS50 | c.942+36C>T | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as rs1038296670, COSV99298486; called by muse, mutect2, varscan2
